Somatic mutation profile of tumor specimen TCGA-05-4384-01A (aliquot TCGA-05-4384-01A-01D-1753-08) from TCGA case TCGA-05-4384, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.8 years (24,411 days).
Specimen TCGA-05-4384-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f099efdd-6021-4afd-9748-733e5056c0a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4384-10A (Blood Derived Normal), aliquot TCGA-05-4384-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/683d979f-0ced-4839-b61b-c26f065c1da6

The open-access MAF lists 141 somatic variants for this specimen: 104 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 34, Nonsense Mutation 7, Frame Shift Del 4, RNA 1, 3'UTR 1, Frame Shift Ins 1, Intron 1, Splice Site 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMC3 | c.3181del p.D1061Tfs*20 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | catalogued as rs1554789671; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- RIT1 | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs483352822, CM136419, CM148229, COSV64170809, COSV64170843, COSV64170960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMO | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 51/251 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV50824415; called by muse, mutect2, varscan2
- AADACL4 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.827); catalogued as rs1235019904, COSV66105858; called by muse, mutect2, varscan2
- AKAP13 | c.6710G>A p.S2237N (on ENST00000394518 / NM_007200.5; = p.S2241N on NM_006738.6) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.31); catalogued as COSV63449050; called by muse, mutect2
- APBA2 | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV67104183, COSV67104217; called by muse, mutect2, varscan2
- ARGFX | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1171684808, COSV100544226, COSV57681617; called by muse, mutect2, varscan2
- BAZ2A | c.1805T>A p.V602E | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV51631953; called by muse, mutect2, varscan2
- BRD9 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs573189640, COSV100056914; called by muse, mutect2, varscan2
- BRD9 | c.1620G>T p.E540D | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100056916; called by muse, mutect2, varscan2
- BRINP2 | c.1622G>A p.W541* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV64175508; called by muse, mutect2
- CC2D1B | c.1120A>T p.T374S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV52558785; called by muse, mutect2, varscan2
- CD22 | c.1105A>C p.N369H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV50049694; called by muse, mutect2, varscan2
- CDH8 | c.2015G>A p.G672E | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54849900; called by muse, mutect2, varscan2
- CEP170 | c.1046G>T p.R349I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100316529; called by mutect2, varscan2
- CFAP65 | c.4588A>T p.R1530W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV58558213; called by muse, mutect2, varscan2
- CHKB | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV56415153; called by muse, mutect2, varscan2
- CHKB | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs889845523, COSV56415158; called by muse, mutect2, varscan2
- CHML | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs920004999, COSV59362611; called by muse, mutect2, varscan2
- CHRNA4 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100937362; called by muse, mutect2, varscan2
- CHRNA4 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as COSV100937364; called by muse, mutect2, varscan2
- CLPB | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.73); catalogued as COSV53627535; called by muse, varscan2
- CTNNB1 | c.2330T>C p.F777S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as COSV62690532; called by muse, mutect2
- CTPS1 | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65451808; called by muse, mutect2, varscan2
- CTSZ | c.362A>T p.Q121L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53882454; called by muse, mutect2, varscan2
- CUL7 | c.1480T>C p.W494R | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54813335; called by muse, mutect2, varscan2
- DSC2 | c.2250G>T p.V750= | Splice Region (SNP) | VAF 18/71 reads (25%) | catalogued as COSV51861353; called by muse, mutect2, varscan2
- DST | c.14891T>C p.V4964A (on ENST00000361203 / NM_001374722.1; = p.V2552A on NM_015548.5) | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV54999057; called by muse, mutect2
- ERBB2 | c.1899-2A>T p.X633_splice | Splice Site (SNP) | VAF 41/152 reads (27%) | catalogued as rs112734930, COSV54063932; called by muse, mutect2, varscan2
- EXOSC10 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV58663767; called by muse, mutect2, varscan2
- FAT3 | c.4898C>A p.T1633K | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as COSV53078734, COSV53145827; called by muse, mutect2, varscan2
- FBXO22 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100380487; called by muse, mutect2, varscan2
- FGF23 | c.578T>A p.L193Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52975166; called by muse, mutect2
- FMN2 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as COSV60418155; called by muse, mutect2
- GALR1 | c.1050A>C p.*350Cext*1 | Nonstop Mutation (SNP) | VAF 9/131 reads (7%) | catalogued as COSV55315979; called by muse, mutect2
- GPRIN1 | c.3013C>A p.P1005T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV56134856; called by muse, mutect2, varscan2
- GZMH | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs1395701040, COSV53537653; called by muse, mutect2, varscan2
- HMGB4 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV53882242; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1525G>T p.V509F | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54560251; called by muse, mutect2, varscan2
- IRF7 | c.640T>C p.W214R (on ENST00000397566; = p.W201R on NM_001572.5) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.628); catalogued as COSV99199602; called by muse, mutect2, varscan2
- ISL1 | c.235T>A p.C79S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV57932257; called by muse, mutect2, varscan2
- ITGAX | c.1898C>G p.P633R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as COSV51641858; called by muse, mutect2
- KCNA1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV66836601; called by muse, mutect2, varscan2
- KDR | c.2003C>A p.T668K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV55758446, COSV55759998; called by muse, mutect2, varscan2
- KEAP1 | c.1570G>T p.G524C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50262369; called by muse, mutect2, varscan2
- KIF21B | c.1555G>T p.A519S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1558016958, COSV59752758; called by muse, mutect2, varscan2
- KIF5A | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.618); catalogued as COSV54051854; called by muse, mutect2, varscan2
- KLHL11 | c.1457C>T p.S486L | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.646); catalogued as rs782685633, COSV59861395; called by muse, mutect2, varscan2
- KRTAP6-3 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 12/67 reads (18%) | PolyPhen probably damaging (0.999); catalogued as COSV66963335, COSV99060498; called by muse, mutect2, varscan2
- MMP12 | c.292C>A p.H98N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV58259114; called by muse, mutect2, varscan2
- MUC5AC | c.15370C>T p.P5124S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.997); catalogued as COSV100611330; called by muse, mutect2, varscan2
- MXRA5 | c.2957C>G p.S986* | Nonsense Mutation (SNP) | VAF 4/73 reads (5%) | catalogued as COSV54224599, COSV54230035; called by muse, mutect2
- NAV3 | c.5124G>T p.E1708D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99887618; called by muse, mutect2
- NMT1 | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51960005, COSV99364633; called by muse, mutect2, varscan2
- NRXN3 | c.435G>T p.Q145H (on ENST00000557594 / NM_001272020.2; = p.Q777H on NM_004796.6) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV99816502; called by muse, mutect2
- OR10AG1 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV56631561, COSV99044230; called by muse, mutect2, varscan2
- OR14A16 | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV62926150; called by muse, mutect2, varscan2
- OR2B11 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750162732, COSV59509298; called by muse, mutect2, varscan2
- OR52N2 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV57676194, COSV57677931; called by muse, mutect2, varscan2
- OR8H1 | c.572C>A p.T191K | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100476878; called by muse, mutect2, varscan2
- PADI4 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs771622911, COSV64923075; called by muse, mutect2, varscan2
- PAPPA2 | c.5329C>A p.L1777M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.308); catalogued as COSV62791197; called by muse, mutect2, varscan2
- PARD3 | c.3724C>T p.Q1242* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV61048834; called by muse, mutect2, varscan2
- PARP10 | c.1706T>C p.V569A | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV57296782; called by muse, mutect2, varscan2
- PCDH8 | c.3043C>A p.Q1015K | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV58810914; called by muse, mutect2, varscan2
- PDGFD | c.1058A>G p.Q353R | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.988); catalogued as COSV100159674, COSV56369111; called by muse, mutect2, varscan2
- PDZD2 | c.3400G>A p.E1134K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as COSV56851373; called by muse, mutect2, varscan2
- PLXNA2 | c.4006C>T p.R1336W | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs774681134, COSV65437819; called by muse, mutect2, varscan2
- PLXNA4 | c.2516C>A p.P839H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.778); catalogued as COSV58106556, COSV58163307; called by muse, mutect2, varscan2
- PNPLA3 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV53377296, COSV99336845; called by muse, mutect2, varscan2
- PPARG | c.1067C>A p.T356K (on ENST00000287820 / NM_015869.5; = p.T326K on NM_005037.7) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV55141087; called by muse, mutect2, varscan2
- PPFIA4 | c.1549G>C p.V517L (on ENST00000447715; = p.V492L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55311920, COSV55322058; called by muse, mutect2
- PRKX | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53322263, COSV53327057; called by muse, mutect2, varscan2
- PTGFR | c.707A>T p.Q236L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV66114409; called by muse, mutect2, varscan2
- QRFPR | c.445C>A p.H149N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as COSV57675351; called by muse, mutect2, varscan2
- RYR2 | c.4610C>A p.T1537K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63663874; called by muse, mutect2, varscan2
- SAMSN1 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV53467776, COSV53468179; called by muse, mutect2, varscan2
- SAP30BP | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53126778; called by muse, mutect2
- SHROOM3 | c.4015A>T p.T1339S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.011); catalogued as COSV56023581; called by muse, mutect2, varscan2
- SLC30A6 | c.664A>G p.N222D | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as rs1167044329, COSV50871917; called by muse, mutect2, varscan2
- SLC36A2 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV58862140; called by muse, mutect2, varscan2
- SLITRK1 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV65674370; called by muse, mutect2, varscan2
- SQSTM1 | c.829A>G p.S277G | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV52971916; called by muse, mutect2, varscan2
- SRSF1 | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV99365235; called by muse, mutect2
- SYT1 | c.543C>A p.Y181* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV54034588, COSV54044449; called by muse, mutect2, varscan2
- TENT5A | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100198781; called by muse, mutect2
- TM2D3 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 17/230 reads (7%) | catalogued as COSV60107507, COSV60109760; called by muse, mutect2
- TMC5 | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 31/122 reads (25%) | catalogued as COSV101196608, COSV66869188; called by muse, mutect2, varscan2
- TNKS2 | c.3400C>G p.L1134V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65414732; called by muse, mutect2, varscan2
- TNNI3 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1336537568, COSV61275268; called by muse, mutect2, varscan2
- TRPC1 | c.656G>A p.C219Y (on ENST00000476941 / NM_001251845.2; = p.C185Y on NM_003304.4) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56423024; called by muse, mutect2, varscan2
- TRPM6 | c.4132G>T p.D1378Y | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.04); catalogued as COSV100666146; called by muse, mutect2
- TSHZ2 | c.1868C>A p.A623D | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs902035318, COSV61586952; called by muse, mutect2, varscan2
- TTLL5 | c.1695G>T p.R565S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV54028317; called by muse, mutect2, varscan2
- TXNDC2 | c.434A>T p.K145I (on ENST00000306084 / NM_001098529.2; = p.K78I on NM_032243.6) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60152126; called by muse, varscan2
- XYLT1 | c.2519C>A p.A840E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV104372365, COSV54477881; called by muse, mutect2, varscan2
- ZAN | c.1781C>A p.P594H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs1321406548, COSV61805323; called by muse, mutect2, varscan2
- ZNF285 | c.65T>A p.L22Q | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58408057; called by muse, mutect2, varscan2
- ZNF804A | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as COSV56436414, COSV56441451; called by muse, mutect2, varscan2
- ALDH6A1 | c.5dup p.A3Gfs*48 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- ALMS1 | c.2433_2440del p.Y811* | Frame Shift Del (DEL) | VAF 29/135 reads (21%) | called by mutect2, pindel, varscan2
- DOT1L | c.1565del p.N522Tfs*35 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TTC7A | c.1199_1200del p.S400* | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- ACAN | c.279C>A p.R93= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV61356453, COSV61358304; called by muse, mutect2, varscan2
- BBS7 | c.804G>A p.V268= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs781560954, COSV52654731; called by muse, mutect2, varscan2
- CDH24 | c.2145C>G p.G715= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99943503; called by muse, mutect2, varscan2
- CLCN1 | c.1260C>A p.P420= | Silent (SNP) | VAF 61/303 reads (20%) | catalogued as COSV58367595; called by muse, mutect2, varscan2
- CSMD2 | c.9063G>A p.G3021= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV53882229; called by muse, mutect2, varscan2
- ECT2L | c.132A>G p.Q44= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV62882823; called by muse, mutect2, varscan2
- FAM117B | c.1636C>T p.L546= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV57416637; called by muse, mutect2, varscan2
- GALR1 | c.771A>G p.G257= | Silent (SNP) | VAF 33/228 reads (14%) | catalogued as COSV55315971; called by muse, mutect2, varscan2
- GLRX | c.291G>T p.T97= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99428113; called by muse, mutect2, varscan2
- GRIK2 | c.1113C>G p.L371= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV59713562; called by muse, mutect2, varscan2
- IGHV3-23 | c.336A>C p.V112= | Silent (SNP) | VAF 55/511 reads (11%) | called by muse, mutect2, varscan2
- KDM4D | c.564G>C p.T188= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as COSV58633644; called by muse, mutect2, varscan2
- KEL | c.1335G>T p.A445= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs751855900, COSV100786892, COSV62335129; called by muse, mutect2, varscan2
- KIF5B | c.2406C>G p.L802= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV56650959; called by muse, mutect2, varscan2
- LSS | c.399A>T p.S133= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV100710820; called by muse, mutect2
- MYO7B | c.1983G>A p.K661= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV67344714; called by muse, mutect2, varscan2
- NMT1 | c.810G>T p.R270= | Silent (SNP) | VAF 35/159 reads (22%) | catalogued as COSV99364635; called by muse, mutect2, varscan2
- NRROS | c.153G>T p.V51= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV60744700; called by muse, mutect2, varscan2
- OR14C36 | c.732G>T p.L244= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs764518847, COSV58600520; called by muse, mutect2, varscan2
- OR2T6 | c.42C>T p.L14= | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as rs1558307658, COSV63215747; called by muse, mutect2, varscan2
- OSBP | c.699A>T p.T233= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV55660971; called by muse, mutect2, varscan2
- PDCD11 | c.753A>G p.G251= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV63933095; called by muse, mutect2, varscan2
- PDGFRA | c.2943T>A p.R981= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV57265003; called by muse, mutect2, varscan2
- PRKAB2 | c.231G>A p.R77= | Silent (SNP) | VAF 72/448 reads (16%) | catalogued as COSV54214680; called by muse, mutect2, varscan2
- PUS7L | c.423C>T p.A141= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV61261224; called by muse, mutect2, varscan2
- RP1L1 | c.6174G>A p.P2058= | Silent (SNP) | VAF 65/261 reads (25%) | catalogued as rs200660179, COSV66751963; ClinVar: benign; called by muse, mutect2, varscan2
- SKIV2L | c.1134G>C p.G378= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV64810215; called by muse, mutect2, varscan2
- SYT6 | c.855G>T p.V285= (on ENST00000610222 / NM_001366225.1; = p.V200= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV65772491; called by muse, mutect2, varscan2
- TMC5 | c.606G>T p.L202= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV101196607; called by muse, mutect2, varscan2
- TMEM202 | c.366T>C p.F122= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV58981835; called by muse, mutect2, varscan2
- TNP1 | c.114G>A p.L38= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as rs1309036875, COSV52696424, COSV99378655; called by muse, mutect2, varscan2
- XAB2 | c.1380G>T p.T460= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV50330978; called by muse, mutect2, varscan2
- ZFHX4 | c.4188G>A p.K1396= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs564331284, COSV50506997; called by muse, mutect2, varscan2
- ZNF804B | c.2046C>A p.I682= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV60817096; called by muse, mutect2, varscan2
- DHRS2 | c.*27T>A | 3'UTR (SNP) | VAF 33/132 reads (25%) | catalogued as COSV51630545; called by muse, mutect2, varscan2
- SPG7 | c.1303+4179G>T | Intron (SNP) | VAF 26/306 reads (8%) | catalogued as COSV99244657; called by muse, mutect2
- SSPOP | n.1975C>T | RNA (SNP) | VAF 6/46 reads (13%) | catalogued as rs767080584, COSV50486434; called by muse, mutect2
